CCDI case PBBXIX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/094ec657-120a-4bdd-9473-ed2072ee713e

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neuroma, NOS: ICD-O-3 morphology code: 9570/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,566 days).

Biospecimens (3 samples)
- Sample 0DK5H2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK5H8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DK5HN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
